Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TH, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TH-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology
REVISED REPORT (Addendum/Procedure included)
Requested By:

ICD - 0 - 3
adenocarcinoma, NOS 8140/3
Site: lung, lower lobe C34.3

SLIDE DISPOSITION:

DIAGNOSIS:

A. Lung, left lower lobe #1, wedge resection: Invasive adenocarcinoma (largest focus of invasion less than 0.5 cm), with an otherwise prominent lepidic growth pattern, forming a poorly circumscribed 2.0 x 1.5 x 1.2 cm mass. Visceral pleural invasion is absent. Angiolymphatic invasion is absent. The non-neoplastic lung parenchyma is unremarkable. The surgical margin is negative for tumor (by 0.5 cm).

B. Lung, left upper lobe, wedge resection: Necrotizing granuloma. Stains for microorganisms will be reported in an addendum.

C. Lymph node, left interlobar (station 11L) set #1, biopsy: A single (1) lymph node is negative for malignancy.

D. Lymph node, left interlobar (station 11L) set #2, biopsy: A single (1) lymph node is negative for tumor.

E. Lymph node, subcarinal (station 7), biopsy: A single (1) lymph node is negative for tumor.

F. Lung, left lower lobe #2, wedge resection: Negative for residual malignancy. Bronchial margin is negative for tumor. Multiple (12) intrapulmonary/peribronchial (IPPB) lymph nodes are negative for malignancy.

G. Lymph node, subaortic (station 5), biopsy: A single (1) benign lymph node with an adjacent calcified granulomas.

With available surgical material, [AJCC pT1aNO] (7th edition,

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

ADDENDUM:

GMS stain reveals fungal organisms consistent with Histoplasma species. AFB is negative.

Transcribed by:

Signed by

GROSS DESCRIPTION:

A. Received fresh labeled "left lower lobe of the lung" is an 8.2 x 2.3 x 1.7 cm lung wedge resection. There is a 2.0 x 1.5 x 1.2 cm ill-defined solid mass located 0.5 cm from the stapled margin. The mass does not umbilicate the visceral pleura. Representative

[page 2 of 2]
sections are submitted. Grossed by

B. Received fresh labeled "left upper lobe of lung" is a 4.5 x 1.5 x 1.3 cm lung wedge resection. There is a 1.5 x 1.5 x 1.5 cm well-circumscribed solid mass located 0.3 cm from the stapled margin. The mass umbilicates the visceral pleura which is inked and submitted perpendicularly. Representative sections are submitted. Grossed by :

C. Received fresh labeled "station 11 left lymph node" is a 0.9 x 0.8 x 0.3 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by .

D. Received fresh labeled "station 11 left lymph node, set 2" is a 0.8 x 0.4 x 0.3 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by

E. Received fresh labeled "station 7 lymph node" is a 0.9 x 0.4 x 0.3 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by

F. Received fresh labeled "left lung lower lobe" is a 150.0 gram completion lobectomy. No masses are identified. Multiple intrapulmonary, peribronchial lymph nodes are identified. Representative sections are submitted. Grossed by

G. Received fresh labeled "station #5 lymph node" is a 1.8 x 1.0 x 0.8 cm aggregate of fragmented lymphatic tissue, which is entirely submitted. Grossed by

BLOCK SUMMARY:

Part A: Left lower lobe of the lung

- 1 LLL lung 1
- 2 LLL lung 2

Part B: Left upper lobe of lung

- 1 LUL lung nodule 1
- 2 LUL lung nodule 2

Part C: Station #11 left lymph node

- 1 Station #11 left LN (C1)

Part D: Station #11 left lymph node set #2

- 1 Station #11 Lt LN set #2(D1)

Part E: Station #7 lymph node

- 1 Station #7 LN (E1)

Part F: Left lung lower lobe

- 1 Uninvolved lung
- 2 Bronchial margin
- 3 Peribronchial LNs 1(F1)
- 4 Peribronchial LNs 1(F2)
- 5 Peribronchial LNs 5(F3)
- 6 Peribronchial LNs 4(F4)

Part G: Station #5 lymph node

- 1 Station 5 LN (G1)
-

Source: NCI Genomic Data Commons file 28579169-3e68-4557-8702-4a0935c034c0 (TCGA-MP-A4TH.842ADC9F-9FEE-49DC-A95D-37FCBF8FB764.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).